Gene-level copy-number profile of tumor specimen C3N-01719-04 from CPTAC case C3N-01719, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 63.2 years (23,073 days).
Specimen C3N-01719-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 20d850f3-0672-4da7-8326-cda1e112b51b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01719-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,218 have no estimate.
https://portal.gdc.cancer.gov/files/ecf87b18-56ad-408d-99c9-f77bc92ed3e8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 130; copy number 2: 57,951; copy number 3: 274; copy number 5: 50.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 50 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:35,038,625–35,875,194, 50 genes, copy number 5: AL353795.3, C9orf131, RN7SL338P, VCP, FANCG, PIGO, AL353795.2, STOML2, FAM214B, AL353795.1, UNC13B, AL160274.1, ATP8B5P, ZFAND6P1, RUSC2, AL133476.1, RPL36AP33, FAM166B, RPS29P17, TESK1, MIR4667, CD72, AL357874.2, AL357874.1, SIT1, RMRP, RMRP, CCDC107, ARHGEF39, RN7SL22P, CA9, TPM2, TLN1, MIR6852, CREB3, MIR6853, GBA2, RGP1, MSMP, AL133410.2, AL133410.1, NPR2, SPAG8, HINT2, AL133410.3, TMEM8B, FAM221B, OR13E1P, OR13J1, NDUFA5P4.

Autosomal genes at a single copy (total copy number 1): 130. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
